Gene-level copy-number profile of tumor specimen TCGA-CD-8529-01A from TCGA case TCGA-CD-8529, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 65.7 years (23,979 days).
Specimen TCGA-CD-8529-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.436cc7ca-158c-4a98-ae61-a5fe8f43b42b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CD-8529-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/29c770ce-aa37-4bbc-bafe-9afce0a32c1d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 6,100; copy number 2: 34,958; copy number 3: 12,930; copy number 4: 4,645; copy number 5: 583; copy number 6: 589.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CD-8529-01A-11D-2338-01): tumor purity 0.99, ploidy 2.02, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,172 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:158,254,424–161,699,607, 171 genes, copy number 5 (broad region; genes not listed).
- chr5:58,198–15,384,853, 273 genes, copy number 5–6 (broad region; genes not listed).
- chr13:90,493,287–91,354,579, 14 genes, copy number 5 (within-gene range 4–5): LINC01049, RNU6-75P, LINC00410, BRK1P2, LINC00380, LINC00379, PPIAP23, MIR17HG, MIR17, MIR18A, MIR19A, MIR20A, MIR19B1, MIR92A1.
- chr13:104,814,327–106,961,392, 27 genes, copy number 6: RPL7P45, AL138954.1, DAOA-AS1, AL359751.2, AL359751.1, DAOA, AL359745.1, LINC00343, AL138701.1, AL138701.2, RNA5SP38, AL139379.1, LINC00460, RPL35P9, EFNB2, AL138689.2, AL138689.1, ARGLU1, LINC00551, LINC00443, ATP5MC1P5, AL163534.1, AL162574.2, PPIAP24, AL162574.1, AL162574.3, AL354741.1.
- chr13:109,101,261–114,337,626, 120 genes, copy number 6 (broad region; genes not listed).
- chr15:92,393,881–101,933,350, 209 genes, copy number 5 (broad region; genes not listed).
- chr20:49,632,945–64,313,132, 358 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 5,559. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
